Somatic mutation profile of tumor specimen TCGA-BJ-A28S-01A (aliquot TCGA-BJ-A28S-01A-11D-A19J-08) from TCGA case TCGA-BJ-A28S, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 79.8 years (29,143 days).
Specimen TCGA-BJ-A28S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8e56b77-4a86-4d7f-bc88-62ac427a17b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A28S-10A (Blood Derived Normal), aliquot TCGA-BJ-A28S-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d8f3b6d-7fb1-4bd4-b885-9ec4e0e40fe0

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATR | c.3037C>G p.L1013V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs755521280, COSV63390852; called by muse, mutect2, varscan2
- BRWD1 | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV58123542; called by muse, mutect2, varscan2
- C8orf34 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs772994743, COSV61376963; called by muse, mutect2, varscan2
- CFAP47 | c.2158-2A>T p.X720_splice | Splice Site (SNP) | VAF 14/15 reads (93%) | catalogued as COSV52890422; called by muse, mutect2
- ESPL1 | c.1728G>T p.W576C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV57762432; called by muse, varscan2
- KSR2 | c.2405C>T p.T802M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563602140, COSV56674686; called by muse, mutect2
- LAMA4 | c.1781C>A p.A594E (on ENST00000230538 / NM_001105206.3; = p.A587E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV57903464; called by muse, mutect2, varscan2
- MEGF6 | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53894865; called by muse, mutect2, varscan2
- MSLNL | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs369732940; called by muse, mutect2, varscan2
- MYOF | c.2930A>G p.D977G | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63709455; called by muse, mutect2, varscan2
- NDFIP2 | c.541A>T p.T181S | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV54529806; called by muse, mutect2, varscan2
- SP4 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56025880; called by muse, mutect2
- ZNF624 | c.2570T>A p.I857K | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV60941253; called by muse, mutect2, varscan2
- RBM6 | c.105del p.K36Rfs*33 | Frame Shift Del (DEL) | VAF 62/174 reads (36%) | called by mutect2, pindel, varscan2
- SVIL | c.4802del p.S1601Mfs*13 (on ENST00000355867 / NM_021738.3; = p.S1175Mfs*13 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- ZBTB7C | c.1185_1198delinsAT p.I396_R400delinsC | In Frame Del (DEL) | VAF 54/163 reads (33%) | called by pindel, varscan2*
- AGO1 | c.1917C>T p.D639= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as COSV64596273; called by muse, mutect2, varscan2
- CCKBR | c.801C>T p.G267= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as rs1233227644, COSV58102917; called by muse, mutect2
- EXOC3L2 | c.2145C>T p.L715= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as rs923325123, COSV52974383; called by muse, mutect2, varscan2
